Somatic mutation profile of tumor specimen ALCH-B0FP-TTP1-A (aliquot ALCH-B0FP-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0FP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.7 years (27,272 days).
Specimen ALCH-B0FP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 227e2405-6b4f-46d8-ad3e-fec8d86652e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0FP-NB1-A (Blood Derived Normal), aliquot ALCH-B0FP-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0d67b0b-359e-425a-8e19-cca3adad902c

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 30/517 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- CCDC62 | c.1228C>G p.P410A | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV53432291; called by muse, mutect2
- PKD1L2 | c.1298C>A p.T433N | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs1166649179; called by muse, mutect2
- SLITRK2 | c.1802C>A p.S601* | Nonsense Mutation (SNP) | VAF 16/257 reads (6%) | catalogued as COSV59422879; called by muse, mutect2
- WDFY3 | c.3767G>A p.R1256H | Missense Mutation (SNP) | VAF 11/344 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.339); catalogued as rs1291839727, COSV99886664; called by muse, mutect2
- C9orf43 | c.1209C>A p.D403E | Missense Mutation (SNP) | VAF 20/472 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.189); called by muse, mutect2
- GPLD1 | c.994A>C p.N332H | Missense Mutation (SNP) | VAF 29/772 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.166); called by muse, mutect2
- IFFO2 | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 12/293 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.092); called by muse, mutect2
- MUC15 | c.173A>G p.D58G | Missense Mutation (SNP) | VAF 20/480 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.037); called by muse, mutect2
- PDHX | c.956T>G p.L319R | Missense Mutation (SNP) | VAF 22/626 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RAB11FIP4 | c.1066A>T p.N356Y | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2
- RAG1 | c.1710G>C p.L570F | Missense Mutation (SNP) | VAF 19/349 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SYT3 | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 13/329 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- DNAH11 | c.258C>T p.N86= | Silent (SNP) | VAF 16/402 reads (4%) | called by muse, mutect2
- SPEN | c.4584T>C p.S1528= | Silent (SNP) | VAF 18/654 reads (3%) | catalogued as rs1176664413; called by muse, mutect2
